Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5470, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5470-01A (Primary Tumor).

[page 1 of 4]
Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

Report Status: Amend/Addenda

TCGA-CZ-5470

CASE: [REDACTED]
PATIENT: [REDACTED]

Resident: [REDACTED]
Pathologist: [REDACTED]

PATHOLOGIC DIAGNOSIS:

A. SPECIMEN DESIGNATED "LEFT KIDNEY":

RENAL CELL CARCINOMA (7.1 cm), clear cell, Fuhrman nuclear grade III/IV, arising in the lower pole with a region of oncocytoma-like architecture.

Tumor is confined to the kidney.

Soft tissue resection margins are negative for tumor.

Artery, vein, and ureter margins are negative for tumor.

No lymphovascular invasion is seen.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

NOTE: Dr. [REDACTED] Pathology Service, has reviewed this part of the case and concurs.

B. SPECIMEN DESIGNATED "LEFT ADRENAL":

Adrenal cortical adenoma (2.0 cm), with myolipomatous metaplasia, mucin, and vascular sclerosis.

Adrenal cortical medullary multinodular hyperplasia.

No necrosis.

No atypia.

Mitoses number <1:10 HPF.

NOTE: [REDACTED] Endocrine Pathology Service, has reviewed the case and concurs.

C. SPECIMEN DESIGNATED "REGIONAL LYMPH NODES":

Two lymph nodes, negative for tumor (0:2).

CLINICAL DATA:

History: Not provided.

Operation: Left nephrectomy.

Operative Findings: Not provided.

Clinical Diagnosis: Not provided.

TISSUE SUBMITTED:

A/1. Left kidney.

B/2. Left adrenal.

C/3. Regional lymph node.

GROSS DESCRIPTION:

The specimen is received fresh, in three parts, each labeled with the patient's name and unit number.

Part A, "left kidney", consists of a radical nephrectomy specimen (416 g) including a kidney (15.3 x 7.5 x 5.5 cm) with a bifurcated renal vein (1.8 cm length x 0.5 and 1.0 cm diameter), a renal artery (2.8 cm length x 0.5 cm diameter), and two ureters (7.8 cm length x 0.3 cm diameter and 8.0 cm length x 0.3 cm diameter). Gerota's fascia is intact and is inked black. A tan/red, cystic, hemorrhagic, encapsulated mass (7.1 x 5.0 x 4.5 cm) is located in the lower pole, 0.1 cm from Gerota's fascia, 4.2 cm from the artery margin, 4.5 cm from the vein margin, and 9.5 cm from the closest ureter margin. Within the mass, there is a region of tan/white, homogeneous tumor (1.8 cm greatest

[page 2 of 4]
Pathology Report

dimension) that is designated T2. The remainder of the mass is designated T1. Representative sections of the mass are submitted for cytogenetics, quick fix, tissue banking, and to Dr. Signoretti's lab. Representative sections of nonneoplastic kidney are submitted to the tissue bank and put on hold for immunofluorescence and electron microscopy. No lymph nodes are identified. No adrenal tissue is identified. Gross photographs are taken.

Micro A1: Ureter, artery, vein margins, en face, 4 frags, [REDACTED]
Micro A2: Mass, T1 with respect to T2, 1 frag, [REDACTED]
Micro A3: Mass with respect to kidney parenchyma to include T1 and T2, 1 frag, [REDACTED]
Micro A4: Mass with respect to fascia, 1 frag, [REDACTED]
Micro A5: Nonneoplastic kidney cortex, 1 frag, [REDACTED]

Part B, "#2. Left adrenal", consists of an adrenal gland (15.58 g, 6.2 x 4.3 x 1.5 cm) with attached adipose tissue. The cortex is expanded (up to 1.7 cm) and has a yellow/tan, circumscribed region (1.4 x 1.2 x 1.1 cm). A gross photograph is taken. The outer surface of the specimen is selectively inked black near the expanded region. The entire specimen is submitted for histologic examination.

Micro B1-B2: Medullary cavity, greatest dimension, submitted in two cassettes, 1 frag each, [REDACTED]
Micro B3-B4: Remainder expanded medulla, 1 frag each, [REDACTED]
Micro B5-B8: Remainder of adrenal gland, 2-3 frags each, [REDACTED]
Micro B9-B10: Remainder of specimen, multi frags each, [REDACTED]

Part C, "#3. Regional lymph node", consists of two fragments of yellow/tan fibroadipose tissue (2.0 x 1.0 x 0.4 cm aggregate) with two smooth, brown/tan lymph nodes (0.5 x 0.4 x 0.1 cm and 0.4 x 0.2 x 0.1 cm). The entire specimen is submitted for histologic examination.

Micro C1: 2 frags, [REDACTED]

CASE NUMBER: [REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by [REDACTED]

ADDENDUM:

RENAL PATHOLOGY EVALUATION OF THE KIDNEY PARENCHYMA:

LEFT KIDNEY (RADICAL NEPHRECTOMY)

GLOMERULOPATHY WITH A MEMBRANOUS PATTERN OF INJURY, WITH NUMEROUS SUBEPITHELIAL ELECTRON DENSE DEPOSITS BY ULTRASTRUCTURAL ANALYSIS; THE DEPOSITS SHOW A RESTRICTED IMMUNOREACTIVITY FOR IgG/KAPPA, SUGGESTIVE OF A PARAPROTEIN DEPOSITION DISEASE (SEE NOTE)

MODERATE CHRONIC CHANGES OF THE PARENCHYMA, INCLUDING:

- FOCAL GLOBAL GLOMERULOSCLEROSIS (15% OF GLOMERULI)
- FOCAL TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS (20% OF THE PARENCHYMA)
- ARTERIAL AND ARTERIOLAR SCLEROSIS, MODERATE

NOTE:

The changes seen in the parenchyma suggest a membranous pattern of injury with [REDACTED]

[page 3 of 4]
Pathology Report

an unusual immunoreactivity of these deposits. The deposits are localized and distributed along the glomerular capillary wall resembling a membranous glomerulopathy, however, the restricted immunoreactivity of the deposits is very unusual and would suggest a paraprotein deposition disease of the IgG/kappa type. It would therefore be prudent to test for circulating paraproteins in this patient. The possibility of a membranous glomerulopathy with an unusual and restricted immunoreactivity of the deposits cannot be ruled out with certainty, however, the diagnosis of idiopathic or tumor-associated membranous glomerulopathy should only be considered in this patient if circulating paraproteins and a plasma cell dyscrasia or other B cell lymphoproliferative disorders have been ruled out.

MICROSCOPIC DESCRIPTION:

The sample consists of renal cortex and medulla not involved by the tumor. There are more than 200 glomeruli present in the sample submitted for evaluation. About 15% of the glomeruli are globally obsolescent (sclerosed). The preserved glomeruli show normal cellularity, without signs of inflammation, fibrinoid necrosis, or sclerosis. The peripheral capillary walls reveal thickened basement membranes, with fine "spike"-like projections and numerous diffusely distributed "crater-like" defects visible in the basement membranes in the Jones silver stain. Tubules show normal cellular details. There are isolated, PAS-positive casts present in some distal tubules. Focal tubular atrophy is seen in areas of interstitial fibrosis. Significant interstitial inflammation is not evident in the sample examined. Approximately 20% of the tissue included in this biopsy shows tubular atrophy, mild mononuclear cell inflammation, and interstitial fibrosis, as evidenced on the trichrome stains (AFOG). Arteries show moderate sclerosis of the media, with focal replacement of smooth muscle cells by connective tissue. Arterioles reveal subintimal hyaline accumulation.

IMMUNOFLUORESCENCE MICROSCOPY REPORT:

KIDNEY # [REDACTED]

The sections were incubated with antibodies specific for the heavy chains of IgG, IgA, and IgM, for kappa light chains, lambda light chains, C3, C1q, albumin, and fibrin-related antigens.

The sample consists of kidney cortex. There are 68 glomeruli present. Eleven (11) glomeruli are globally sclerosed and one (1) glomerulus shows segmental sclerosis. There is diffuse granular deposition of IgG (3+/4+) along the peripheral glomerular capillary walls; these deposits are only reactive for kappa and not lambda light chains. There is dull reactivity for fibrin present along all glomerular capillary walls. Tubules contain reabsorbed proteins (albumin, IgG, C3) in the form of cytoplasmic granules. The interstitium reveals scattered fibrin deposits. Arterioles show focal C3 reactivity. There is no difference noted in the intensity of the staining for kappa and lambda light chains in the casts in the background of the tissue.

ELECTRON MICROSCOPY REPORT:

KIDNEY [REDACTED]

Blocks: 6; Blocks examined: 4 thick sections; 1 thin section.

The tissue examined at the ultrastructural level includes two glomeruli. The glomerular capillary walls are greatly distorted by the presence of numerous subepithelial electron dense deposits and thickening of the basement membranes. The deposits are sparsely distributed and they appear to have been incorporated into the outer aspect of the thickened basement membranes. The electron dense deposits are finely granular but they do not show organized substructures. There is extensive effacement of visceral epithelial cell foot processes present and microvillous degeneration of the epithelial cell membrane. Glomerular endothelial cells appear unremarkable and do not contain tubuloreticular structures. Subendothelial electron dense deposits are not seen. The mesangium shows normal cell elements and an extracellular matrix without electron dense deposits.

[page 4 of 4]
Pathology Report

Accession Number: [REDACTED]
Type: Cytogenetics
Specimen Type: [REDACTED] Solid Tumor
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

Report Status: Final

CASE: [REDACTED]
PATIENT:
Cytogeneticist: [REDACTED]

KARYOTYPE: T1: 46,XX,der(3;5)(q10;q10)[10]
T2: 46,XX,der(3;5)(q10;q10)[10]

METAPHASES COUNTED: 20 ANALYZED: 10 SCORED: 10 BANDING: GTG

INTERPRETATION:

All metaphases for both specimens received contained der(3;5)(q10;q10), a characteristic finding in renal cell carcinomas, clear cell type.

COMMENTS:

This analysis excludes mosaicism greater than 25% at a 95% confidence limit (Prenatal Diagnosis [REDACTED]). Small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

? RCC; kidney tumor; Two specimen were received, labeled #1 and #2.

[REDACTED]

Source: NCI Genomic Data Commons file a5b324f5-b57d-4af2-b0fd-8dc806313280 (TCGA-CZ-5470.A2F05C57-62E6-4DE7-B34C-2AFBC64D0164.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).